TARGET case TARGET-30-PASTKW — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Peripheral nerves and autonomic nervous system. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/75ab3d8a-b5ea-5728-9571-94c852713c57

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Age at index: 1 years; Vital status: Alive.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C47.3; Tissue or organ of origin: Peripheral nerves and autonomic nervous system of thorax; Classification of tumor: primary; Age at diagnosis: 2.0 years (716 days); Year of diagnosis: 2009; Days to last follow up: 3,226 days (8.8 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: Low.
   Pathology details: Necrosis percent: 10; Percent tumor nuclei: 40.
   Treatment given: Protocol identifier: ANBL00B1.
   Treatment given: Protocol identifier: ANBL0032.
   Treatment given: Protocol identifier: ANBL0532.

Follow-up (1 entry)
- Days to follow up: 3,226 days (8.8 years); Event-free: no event (relapse, second malignancy or death) recorded through day 3,226; Year of follow up: 2018.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Normal; Ploidy: Diploid.

Biospecimens (2 samples)
- Sample TARGET-30-PASTKW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PASTKW-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- First Event: Censored
- Overall Survival Time in Days: 3226
- Protocol: ANBL00B1, ANBL0532, ANBL0032
- Ploidy: Diploid (DI=1)
- Ploidy Value: 1
- Histology: Unfavorable
- MKI: Low
- ICDO Description: Peripheral nerves and Autonomic nervous system of thorax Peripheral nerves and Autonomic nervous system of (see list under C47): . Axilla . Chest . chest wall . thoracic wall . infraclavicular region . scapular region Intercostal nerve
- Percent Tumor v/s Stroma: 40/60
